Gene-level copy-number profile of tumor specimen TCGA-74-6584-01A from TCGA case TCGA-74-6584, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.4 years (20,232 days).
Specimen TCGA-74-6584-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.4611efa8-e6fd-4dc2-a737-0b15f1304e86.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-74-6584-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/294003c0-215d-4ee5-be0f-38e10051240b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 4,096; copy number 2: 48,639; copy number 3: 6,255; copy number 4: 13; copy number 5: 137; copy number 6: 12; copy number 7: 500; copy number 8: 18; copy number 23: 41; copy number 25: 2; copy number 27: 5; copy number 39: 3; copy number 42: 9; copy number 48: 2; copy number 49: 12; copy number 50: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-74-6584-01A-11D-1842-01): tumor purity 0.53, ploidy 4.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,367,424–23,438,700, 38 genes: IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.
- chr9:23,690,104–24,592,104, 8 genes (within-gene range 0–1): ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.
- chr10:87,751,512–88,584,530, 11 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 758 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:59,014,354–61,471,087, 42 genes, copy number 5–8 (within-gene range 2–8): AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1.
- chr3:163,109,152–163,361,563, 1 gene, copy number 7 (within-gene range 1–7): LINC01192.
- chr3:164,001,606–187,733,849, 408 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr7:52,891,837–56,578,866, 94 genes, copy number 5–23 (broad region; genes not listed).
- chr7:87,934,143–93,361,123, 75 genes, copy number 5–27 (broad region; genes not listed).
- chr12:67,424,272–67,442,559, 2 genes, copy number 48: NTAN1P3, LINC02420.
- chr12:68,201,349–68,332,381, 3 genes, copy number 39 (within-gene range 2–39): IL26, IL22, MDM1.
- chr12:68,805,011–68,971,570, 9 genes, copy number 42: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:80,583,683–81,261,210, 11 genes, copy number 49: AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699.
- chr12:81,270,669–81,312,422, 1 gene, copy number 49: PPFIA2-AS1.
- chr12:82,223,681–84,672,026, 17 genes, copy number 50: CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC090679.1, AC087888.1, AC093027.1.
- chr12:87,746,567–87,750,313, 2 genes, copy number 25: AC079598.4, CYCSP30.
- chr13:18,467,172–20,962,195, 84 genes, copy number 7 (broad region; genes not listed).
- chr13:36,674,020–36,742,465, 3 genes, copy number 7 (within-gene range 1–7): SERTM1, GAPDHP34, TCEAL4P1.
- chr13:52,033,611–52,132,723, 2 genes, copy number 6 (within-gene range 1–6): NEK5, AL139082.1.
- chr13:60,396,457–60,613,734, 2 genes, copy number 7 (within-gene range 1–7): TDRD3, RNA5SP31.
- chr13:60,636,888–60,733,600, 2 genes, copy number 7: EIF4A1P6, AL161901.1.

Autosomal genes at a single copy (total copy number 1): 4,096. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
